Gene-level copy-number profile of tumor specimen TCGA-VD-A8KG-01A from TCGA case TCGA-VD-A8KG, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, type B; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.7 years (17,417 days).
Specimen TCGA-VD-A8KG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.9cd4879d-aa0e-4b59-93f1-1bb6c24faebc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VD-A8KG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e5890595-7322-45a7-8460-8453feedd28d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 76; copy number 2: 53,031; copy number 3: 3,603; copy number 4: 2,181; copy number 5: 129; copy number 6: 792; copy number 8: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VD-A8KG-01A-11D-A39V-01): tumor purity 0.93, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 922 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:391,752–796,781, 11 genes, copy number 6: IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1.
- chr6:1,623,806–3,984,130, 54 genes, copy number 5–6 (within-gene range 3–6): GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1, AL359852.2, AL359852.1, LINC02521, LINC01600, MYLK4, WRNIP1, SERPINB1, SERPINB9P1, MIR4645, SERPINB9, AL133351.2, AL133351.1, SERPINB6, LINC01011, NQO2, NQO2-AS1, HTATSF1P2, AL133351.4, AL133351.3, FAM136BP, SERPINB8P1, AL031963.2, RIPK1, AL031963.3, RNA5SP201, BPHL, AL031963.1, TUBB2A, TUBB2BP1, LINC02525, TUBB2B, PSMG4, SLC22A23, AL445309.1, AL033523.1, AL033523.2, PXDC1, AL391422.4, AL391422.1, AL391422.3, AL391422.2, FAM50B, AL590004.3, AL590004.2, AL590004.1, TDGF1P4, GLRX3P2, AL138831.3.
- chr6:8,073,360–25,042,170, 233 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr11:130,666,735–130,865,561, 5 genes, copy number 5: MIR8052, LINC02873, AP003486.2, PPP1R10P1, LINC02551.
- chr11:130,866,254–130,870,247, 1 gene, copy number 5: AP003486.1.
- chr11:131,877,680–131,984,661, 2 genes, copy number 6: AP000844.2, AP000844.1.
- chr11:133,783,671–134,378,341, 19 genes, copy number 5 (within-gene range 3–5): LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2.
- chr21:20,998,409–46,665,124, 597 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 76. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
